Somatic mutation profile of tumor specimen ALCH-B2FI-TTP1-A (aliquot ALCH-B2FI-TTP1-A-1-0-D-A77J-36) from ALCHEMIST case ALCH-B2FI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 77.0 years (28,113 days).
Specimen ALCH-B2FI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09e28469-f536-47b5-a0d9-6a65c19fe69b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2FI-NB1-A (Blood Derived Normal), aliquot ALCH-B2FI-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6baa412c-9b44-4f3b-aad3-87d77e6c2e28

The open-access MAF lists 262 somatic variants for this specimen: 181 protein-altering or splice-affecting, 57 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 57, Intron 11, Nonsense Mutation 9, Splice Site 6, RNA 4, 5'UTR 3, 5'Flank 3, 3'UTR 3, Splice Region 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.91G>C p.G31R | Missense Mutation (SNP) | VAF 11/92 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960750, COSV67961406; called by muse, varscan2
- TP53 | c.794T>G p.L265R | Missense Mutation (SNP) | VAF 18/250 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD004355, CM971505, COSV52706540, COSV52732531, COSV53696163; called by muse, mutect2
- ADAMTS6 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66859927; called by muse, mutect2
- AGBL5 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59938633; called by muse, mutect2, varscan2
- ANO9 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as rs545589353; called by muse, mutect2, varscan2
- ARMCX2 | c.1490C>T p.T497I | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57529823; called by muse, mutect2
- BAZ2B | c.3757C>A p.R1253S | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV54276760, COSV99680995; called by muse, mutect2, varscan2
- CASR | c.1682G>C p.R561P (on ENST00000490131; = p.R638P on NM_000388.4) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as CM060891, COSV56140244; called by muse, mutect2, varscan2
- CD5L | c.1041A>G p.G347= | Splice Region (SNP) | VAF 9/33 reads (27%) | catalogued as rs764878157; called by muse, mutect2
- CHMP4C | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1023341969, COSV99794129; called by muse, mutect2
- CSNK1G2 | c.630G>C p.K210N | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV55337737; called by muse, mutect2, varscan2
- CT47B1 | c.426G>C p.Q142H | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs772841825, COSV64890928; called by muse, mutect2
- DCAF12L2 | c.896T>A p.L299Q | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV100758904; called by muse, mutect2
- DPP9 | c.2368G>T p.V790L (on ENST00000598800; = p.V819L on NM_139159.5) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs200615314; called by mutect2, varscan2
- ENPEP | c.1430T>C p.I477T | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54451063; called by muse, mutect2
- EPG5 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as rs1368802413; called by muse, mutect2, varscan2
- F5 | c.5643G>T p.W1881C | Missense Mutation (SNP) | VAF 26/305 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); catalogued as COSV63128146; called by muse, mutect2
- F5 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.5); catalogued as COSV63128782; called by muse, mutect2, varscan2
- FAM149A | c.2132G>A p.R711Q (on ENST00000356371 / NM_001367768.2; = p.R420Q on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1027870844; called by muse, mutect2, varscan2
- FLT3 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.416); catalogued as COSV99607880; called by muse, mutect2, varscan2
- GATA1 | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as COSV64962157; called by muse, mutect2, varscan2
- GDAP2 | c.509A>G p.N170S | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as rs745396046; called by muse, mutect2
- H4C12 | c.260T>A p.V87E | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100694812; called by muse, varscan2
- HMCN1 | c.6737G>A p.R2246K | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as rs1450308181; called by muse, mutect2, varscan2
- HSD3B2 | c.468C>G p.Y156* | Nonsense Mutation (SNP) | VAF 22/169 reads (13%) | catalogued as rs1023246046; called by muse, mutect2, varscan2
- HTR2C | c.180C>G p.I60M | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52224285, COSV99348159; called by muse, mutect2, varscan2
- IGHM | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs772304630; called by muse, mutect2, varscan2
- IRAG1 | c.942del p.M316Wfs*3 | Frame Shift Del (DEL) | VAF 25/247 reads (10%) | catalogued as COSV70212613; called by mutect2, pindel, varscan2
- JAG2 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 104/238 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs587684377; called by muse, varscan2
- KBTBD11 | c.1234G>T p.G412C | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57222915; called by muse, mutect2, varscan2
- KCNIP4 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs1428127678, COSV100749689; called by muse, mutect2, varscan2
- KIF21A | c.4651A>G p.I1551V (on ENST00000361418 / NM_001378440.1; = p.I1538V on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1413375205; called by muse, mutect2, varscan2
- KLF15 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.027); catalogued as rs761703149; called by muse, mutect2
- KMT2B | c.2168G>A p.G723E | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1319017297; called by muse, mutect2, varscan2
- MERTK | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.051); catalogued as COSV54932934; called by muse, mutect2, varscan2
- MMRN1 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV53337049; called by muse, mutect2, varscan2
- MTM1 | c.343-2A>T p.X115_splice | Splice Site (SNP) | VAF 12/192 reads (6%) | catalogued as CS971808; called by muse, mutect2
- MUC17 | c.8830G>T p.E2944* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV60283186; called by muse, mutect2, varscan2
- MYBPC3 | c.1869C>G p.C623W | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as CM115896; called by muse, mutect2, varscan2
- NEUROD1 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 47/275 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs925185201; called by muse, mutect2, varscan2
- NMRK1 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737909; called by muse, mutect2, varscan2
- NPAP1 | c.1717C>A p.P573T | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as COSV61504578, COSV61504721; called by muse, mutect2, varscan2
- PCDHA2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.053); catalogued as rs1562152745, COSV65365566; called by muse, mutect2, varscan2
- PLEKHS1 | c.526C>T p.Q176* (on ENST00000369310 / NM_182601.1; = p.Q182* on NM_024889.5) | Nonsense Mutation (SNP) | VAF 30/132 reads (23%) | catalogued as rs578204824; called by muse, mutect2, varscan2
- POTEE | c.1056-1G>A p.X352_splice | Splice Site (SNP) | VAF 9/200 reads (5%) | catalogued as COSV100387223; called by muse, mutect2
- PPP1R3A | c.2041G>C p.D681H | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV99494080; called by muse, mutect2
- PRDM9 | c.1739A>T p.Y580F | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.46); catalogued as rs1325219491; called by muse, mutect2, varscan2
- PRLHR | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1483118236; called by muse, mutect2, varscan2
- PTPRZ1 | c.6778C>G p.L2260V | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66432334; called by muse, mutect2, varscan2
- PXDNL | c.3673C>T p.R1225W | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs766445859, COSV62485411; called by muse, mutect2
- SAMD9L | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV59083665; called by muse, mutect2, varscan2
- SH2D4B | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs766277193; called by muse, mutect2, varscan2
- SLITRK4 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs1321928717; called by muse, mutect2
- SMC4 | c.2014G>C p.D672H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1306134079; called by mutect2, varscan2
- SMG7 | c.1854G>C p.Q618H | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs757802646; called by muse, mutect2, varscan2
- SORL1 | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753082593, COSV52754564; called by muse, mutect2, varscan2
- SPATA2 | c.1506G>T p.M502I | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs142787562; called by muse, mutect2, varscan2
- SPTA1 | c.2849C>T p.S950L | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV63754882; called by muse, mutect2, varscan2
- SRRM2 | c.6457G>A p.G2153S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs779036102, COSV51940094; called by muse, mutect2, varscan2
- TTC17 | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV50020635; called by muse, mutect2
- TTN | c.45568G>A p.E15190K (on ENST00000591111; = p.E7766K on NM_003319.4) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | PolyPhen probably damaging (0.994); catalogued as COSV59990137; called by muse, mutect2
- TUBGCP5 | c.3061A>G p.M1021V | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as rs1192178458; called by muse, mutect2
- USP54 | c.851G>C p.R284P | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100161313; called by muse, mutect2, varscan2
- VAX2 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52265366; called by muse, mutect2, varscan2
- ZNF729 | c.1430G>C p.R477T | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV62606012; called by muse, mutect2
- ZPLD1 | c.1078C>T p.P360S (on ENST00000466937 / NM_001329788.1; = p.P376S on NM_175056.2) | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1311621126, COSV60353885; called by muse, mutect2
- AACS | c.1867A>G p.T623A | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.323); called by muse, mutect2
- AHNAK2 | c.8791G>T p.E2931* | Nonsense Mutation (SNP) | VAF 62/147 reads (42%) | called by muse, varscan2
- ANKRD53 | c.1151C>A p.T384K | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AQP6 | c.677T>A p.L226Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARF3 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- ARHGAP40 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTN3A2 | c.547A>G p.K183E | Missense Mutation (SNP) | VAF 23/328 reads (7%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.572); called by muse, mutect2
- C4orf54 | c.3080C>A p.P1027H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C4orf54 | c.3079C>A p.P1027T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C7 | c.1750-3T>G | Splice Region (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- CCDC83 | c.518A>G p.Y173C | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CD300A | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, varscan2
- CDKN2A | c.125_150+24del p.X42_splice | Splice Site (DEL) | VAF 14/104 reads (13%) | called by mutect2, pindel
- CEP192 | c.5793G>T p.K1931N | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- CEP290 | c.1222A>T p.K408* | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2, varscan2
- CERS2 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 31/277 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CNKSR2 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- CNKSR2 | c.1163C>G p.S388C | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- CR1 | c.4294G>T p.G1432W | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CRLF2 | c.343T>G p.Y115D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, varscan2
- DCAF4L2 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- DMD | c.8084C>A p.P2695H | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.012); called by muse, mutect2
- DNAH6 | c.1487G>T p.G496V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH9 | c.4839A>T p.L1613F | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DPP6 | c.1127C>T p.P376L (on ENST00000377770 / NM_001364500.2; = p.P314L on NM_001936.5) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- DYSF | c.4277A>G p.E1426G | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- EYA2 | c.1236G>T p.Q412H | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- FAM102A | c.805G>T p.G269W (on ENST00000373095 / NM_001035254.3; = p.G127W on NM_203305.2) | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FASLG | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- FASLG | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- FBLN2 | c.3122C>A p.T1041N | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- FREM2 | c.4566C>G p.F1522L | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GK | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 25/291 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPR141 | c.547T>C p.Y183H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIPK3 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTR1F | c.510T>A p.D170E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- IL5RA | c.931G>C p.A311P | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.439); called by muse, mutect2
- ILF3 | c.1346C>G p.S449C | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ITGAD | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- KALRN | c.5731C>A p.P1911T (on ENST00000360013 / NM_001024660.4; = p.P214T on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.149); called by muse, mutect2
- KCNQ2 | c.1226C>A p.P409H (on ENST00000359125 / NM_172107.4; = p.P399H on NM_004518.6) | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- KCTD8 | c.807C>G p.F269L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- KDM4C | c.832C>A p.H278N | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM4C | c.1334C>G p.S445* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2
- KIF21A | c.4733A>T p.Q1578L (on ENST00000361418 / NM_001378440.1; = p.Q1565L on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- KIF5B | c.2128G>C p.E710Q | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- KIR2DL3 | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.049); called by muse, mutect2
- KIR3DL2 | c.1119G>T p.M373I | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, mutect2
- LGR4 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); called by muse, mutect2
- LRRC8C | c.1952A>G p.Y651C | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MAGEB6 | c.885C>G p.I295M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MAGEL2 | c.2530G>T p.A844S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MAMLD1 | c.2086C>A p.Q696K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2
- MROH1 | c.2992C>T p.Q998* | Nonsense Mutation (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- MUC16 | c.34615T>C p.S11539P | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.186); called by muse, mutect2
- MUC4 | c.5411del p.G1804Vfs*1200 | Frame Shift Del (DEL) | VAF 117/650 reads (18%) | called by mutect2, pindel, varscan2
- MUSK | c.2242A>G p.R748G | Missense Mutation (SNP) | VAF 33/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO10 | c.5479C>G p.L1827V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYT1 | c.2173C>A p.Q725K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NDUFA11 | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- NOTCH1 | c.1985A>G p.Y662C | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTNG1 | c.1312T>C p.C438R | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- OBSCN | c.3599A>G p.Y1200C | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- OBSCN | c.15234G>A p.M5078I | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- OR4C5 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- OR6K6 | c.775G>A p.E259K (on ENST00000368144; = p.E235K on NM_001005184.1) | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.6); called by muse, mutect2
- OTOGL | c.3559T>A p.C1187S (on ENST00000547103; = p.C1178S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OXR1 | c.866A>G p.D289G (on ENST00000442977 / NM_001198532.1; = p.D288G on NM_018002.3) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2
- PHKA1 | c.3104G>T p.G1035V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PIH1D2 | c.446A>T p.H149L | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PKN3 | c.889G>T p.G297W | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2
- PNISR | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2
- POMP | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.01); called by muse, mutect2
- PRPF40A | c.326G>C p.G109A | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- PVALB | c.35T>C p.I12T | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PZP | c.2030C>G p.S677* | Nonsense Mutation (SNP) | VAF 21/198 reads (11%) | called by muse, mutect2, varscan2
- QSER1 | c.4205A>G p.Q1402R (on ENST00000399302; = p.Q1531R on NM_001076786.3) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2
- RABGAP1 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.288); called by muse, mutect2
- RAD54B | c.822G>T p.W274C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RFC1 | c.2440-2A>T p.X814_splice (on ENST00000381897 / NM_001363496.2; = p.X813_splice on NM_002913.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 19/155 reads (12%) | called by muse, mutect2, varscan2
- ROBO4 | c.790G>T p.V264L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, varscan2
- RSPO2 | c.317G>T p.S106I | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- SEPHS1 | c.81G>T p.K27N | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SERPINB6 | c.268G>T p.G90C (on ENST00000612421 / NM_001271823.2; = p.G71C on NM_004568.6) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- SLC11A1 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC17A8 | c.382A>T p.T128S | Missense Mutation (SNP) | VAF 42/305 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- SLC25A13 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLC35A2 | c.705C>G p.N235K | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A10P | n.3129+2T>C | Splice Site (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.899+2T>A p.X300_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- SNX30 | c.745T>G p.L249V | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- SPN | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- SPRY2 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 63/454 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- SRRM2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ST6GALNAC5 | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 46/173 reads (27%) | PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- STC1 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 19/319 reads (6%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.745); called by muse, mutect2
- SYDE2 | c.2437A>G p.I813V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D31 | c.2552A>T p.D851V | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, varscan2
- TIMP4 | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLL1 | c.2363C>G p.P788R | Missense Mutation (SNP) | VAF 25/365 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM132C | c.885G>T p.W295C | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TMEM178B | c.791T>C p.I264T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.647); called by muse, mutect2
- TMEM71 | c.315G>T p.R105S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- TRAPPC12 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- TRIO | c.7753C>T p.Q2585* | Nonsense Mutation (SNP) | VAF 37/323 reads (11%) | called by muse, mutect2, varscan2
- TRPA1 | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPA1 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.35546C>T p.P11849L (on ENST00000591111; = p.P10922L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TXNDC15 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TYSND1 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UNC80 | c.3475G>C p.D1159H | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- USH1C | c.208C>A p.H70N | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- USP27X | c.335G>C p.R112P | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.587); called by muse, mutect2
- ZBTB6 | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2
- ZNF318 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- ABCA1 | c.3711T>C p.Y1237= | Silent (SNP) | VAF 52/346 reads (15%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.1674C>G p.L558= | Silent (SNP) | VAF 27/356 reads (8%) | called by muse, mutect2
- AFG3L2 | c.1704G>A p.K568= | Silent (SNP) | VAF 52/321 reads (16%) | called by muse, mutect2, varscan2
- AHNAK2 | c.8691C>G p.P2897= | Silent (SNP) | VAF 68/174 reads (39%) | called by muse, varscan2
- AMER1 | c.2553C>T p.F851= | Silent (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- ARMC6 | c.393G>A p.A131= (on ENST00000392336; = p.A106= on NM_033415.4) | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs142550268; called by muse, mutect2, varscan2
- CD300A | c.549C>G p.L183= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as rs779562299; called by muse, varscan2
- COL15A1 | c.3222C>A p.P1074= | Silent (SNP) | VAF 40/282 reads (14%) | called by muse, mutect2, varscan2
- COLEC12 | c.2004C>T p.L668= | Silent (SNP) | VAF 21/256 reads (8%) | catalogued as COSV68373476; called by muse, mutect2
- COMMD3 | c.399A>G p.E133= | Silent (SNP) | VAF 17/254 reads (7%) | catalogued as rs773300487; called by muse, mutect2
- CYP2D7 | c.762G>T p.L254= | Silent (SNP) | VAF 39/281 reads (14%) | called by muse, mutect2, varscan2
- CYP4F2 | c.75C>T p.V25= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs142765310; called by muse, mutect2, varscan2
- DYSF | c.3133C>T p.L1045= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- EPHX3 | c.954C>T p.I318= | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as rs149458586; called by muse, mutect2, varscan2
- EVX1 | c.864C>G p.G288= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- FAM149A | c.2133G>T p.R711= (on ENST00000356371 / NM_001367768.2; = p.R420= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- FBXO3 | c.1383C>T p.P461= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs758906046; called by muse, mutect2
- GRAMD1C | c.471A>G p.T157= | Silent (SNP) | VAF 49/179 reads (27%) | catalogued as rs749341206; called by muse, mutect2, varscan2
- H2AC15 | c.264C>T p.I88= | Silent (SNP) | VAF 15/304 reads (5%) | called by muse, mutect2
- HERC2 | c.9060G>A p.T3020= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as rs1322484589; called by muse, mutect2
- HGF | c.1830C>A p.T610= | Silent (SNP) | VAF 38/327 reads (12%) | called by muse, mutect2, varscan2
- HSF1 | c.30G>C p.A10= | Silent (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- IFNA8 | c.348G>T p.L116= | Silent (SNP) | VAF 38/306 reads (12%) | called by mutect2, varscan2
- JCAD | c.2244T>A p.R748= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as rs778961433; called by muse, mutect2, varscan2
- KCNJ12 | c.1084C>T p.L362= | Silent (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- MAGEL2 | c.309G>T p.P103= | Silent (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- MAST2 | c.2883G>A p.L961= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1338563282; called by muse, mutect2, varscan2
- MBD5 | c.648C>T p.G216= | Silent (SNP) | VAF 19/171 reads (11%) | called by muse, mutect2, varscan2
- MYT1 | c.2172C>A p.R724= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- NAV3 | c.6900C>T p.S2300= (on ENST00000397909 / NM_001024383.2; = p.S2278= on NM_014903.6) | Silent (SNP) | VAF 11/185 reads (6%) | called by muse, mutect2
- NIPA1 | c.627C>T p.I209= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs759267223; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR4C15 | c.714G>C p.L238= (on ENST00000314644; = p.L184= on NM_001001920.2) | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100116116; called by muse, mutect2, varscan2
- OXCT1 | c.1263A>G p.K421= | Silent (SNP) | VAF 49/324 reads (15%) | called by muse, mutect2, varscan2
- PCDH8 | c.2547G>A p.V849= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.1374C>T p.S458= | Silent (SNP) | VAF 30/205 reads (15%) | catalogued as rs1047171796, COSV53915304; called by muse, mutect2, varscan2
- PLA2G6 | c.1029G>T p.A343= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1422824235; called by muse, mutect2, varscan2
- POF1B | c.162C>A p.T54= | Silent (SNP) | VAF 18/303 reads (6%) | catalogued as COSV53134092; called by muse, mutect2
- POTEE | c.2310C>A p.P770= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV58233418; called by mutect2, varscan2
- PPP4R3C | c.1663T>C p.L555= | Silent (SNP) | VAF 16/181 reads (9%) | called by muse, mutect2
- PROKR1 | c.822G>A p.K274= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as COSV58138546; called by muse, mutect2, varscan2
- ROBO4 | c.789G>A p.A263= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs143848676, COSV100127736; called by muse, varscan2
- RPS16 | c.120G>A p.E40= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as rs779856962; called by muse, mutect2, varscan2
- SCCPDH | c.15G>A p.Q5= | Silent (SNP) | VAF 14/124 reads (11%) | called by muse, varscan2
- SLC24A2 | c.1614C>A p.T538= | Silent (SNP) | VAF 42/267 reads (16%) | called by muse, mutect2, varscan2
- SLITRK5 | c.2844G>T p.V948= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2
- SLX4 | c.4869G>A p.A1623= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs372206872; ClinVar: likely benign; called by muse, mutect2, varscan2
- TACR1 | c.1026C>A p.L342= | Silent (SNP) | VAF 36/198 reads (18%) | called by muse, mutect2, varscan2
- TBCD | c.3306C>T p.P1102= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as rs762267763; called by muse, mutect2, varscan2
- TNFSF9 | c.81G>A p.L27= | Silent (SNP) | VAF 19/122 reads (16%) | called by muse, mutect2, varscan2
- VIM | c.1101T>C p.D367= | Silent (SNP) | VAF 16/482 reads (3%) | called by muse, mutect2
- ZBTB3 | c.270G>C p.L90= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV67361860, COSV67361987; called by muse, mutect2, varscan2
- ZBTB3 | c.84G>A p.V28= | Silent (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2, varscan2
- ZMAT3 | c.807A>G p.Q269= | Silent (SNP) | VAF 126/505 reads (25%) | called by muse, mutect2, varscan2
- ZNF704 | c.462C>T p.F154= | Silent (SNP) | VAF 28/151 reads (19%) | called by muse, mutect2, varscan2
- ZNF721 | c.735C>T p.V245= (on ENST00000338977; = p.V257= on NM_133474.4) | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV59097830, COSV59097901; called by muse, mutect2
- ZNF729 | c.147G>T p.L49= | Silent (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- ZSCAN4 | c.639C>A p.G213= | Silent (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2
- AC104825.1 | n.1115G>A | RNA (SNP) | VAF 14/65 reads (22%) | catalogued as rs1050266913; called by mutect2, varscan2
- AKR1C8P | c.378+99G>C | Intron (SNP) | VAF 40/205 reads (20%) | called by muse, mutect2, varscan2
- ANKRD18A | chr9:38621180 G>A | 5'Flank (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- ATRNL1 | c.3795+48077C>T | Intron (SNP) | VAF 40/250 reads (16%) | called by muse, varscan2
- BX119917.1 | n.211G>T | RNA (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- C11orf65 | c.*9A>G | 3'UTR (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- C19orf12 | c.-95G>T | 5'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- CACTIN | c.*96G>C | 3'UTR (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- CCN4 | c.-83G>T | 5'UTR (SNP) | VAF 29/177 reads (16%) | catalogued as rs527306428; called by muse, mutect2, varscan2
- CXCL12 | c.267-2613C>A | Intron (SNP) | VAF 33/268 reads (12%) | catalogued as COSV100638879; called by muse, mutect2, varscan2
- DNAI2 | c.1347+137C>A | Intron (SNP) | VAF 66/224 reads (29%) | called by muse, mutect2, varscan2
- KRT8P11 | n.466T>C | RNA (SNP) | VAF 21/113 reads (19%) | called by muse, mutect2, varscan2
- LAMA4 | c.1959+12C>A | Intron (SNP) | VAF 18/179 reads (10%) | called by muse, mutect2, varscan2
- MPP1 | c.102+5456C>A | Intron (SNP) | VAF 11/117 reads (9%) | called by muse, mutect2, varscan2
- NFKBID | c.607-93C>T | Intron (SNP) | VAF 46/200 reads (23%) | called by muse, mutect2, varscan2
- NXF5 | n.1386G>T | RNA (SNP) | VAF 11/196 reads (6%) | called by muse, mutect2
- PARP6 | c.1191+415T>C | Intron (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- PTPN1 | c.-61C>T | 5'UTR (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- RN7SKP78 | chr10:6144991 C>A | 5'Flank (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- RNASET2 | c.446+162G>A | Intron (SNP) | VAF 18/154 reads (12%) | called by muse, mutect2, varscan2
- TRIM8 | c.*807C>A | 3'UTR (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- ZFP36L1 | c.58-643G>C | Intron (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2
- ZNF3 | c.144+135C>G | Intron (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- ZNF559 | chr19:9324226 G>C | 5'Flank (SNP) | VAF 12/136 reads (9%) | catalogued as COSV57835389; called by muse, mutect2
